Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A0XZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A0XZ-01A (Primary Tumor).

[page 1 of 2]
Case Number :

Collection Date :

1CD-0-3

Carcinoma, papillary thyroid, NOS 8240/3
Site: thyroid, NOS C73.9

at 8/11
h

Surgical Pathology Report

Diagnosis:

A: Thyroid; total thyroidectomy

Tumor histologic type: papillary thyroid carcinoma

Tumor size: 2.0 cm (gross), largest in any one slide 1.1 cm

Tumor growth pattern: papillary

Extent of invasion:

Extra-capsular: not identified

Vascular: not identified

Tumor multicentricity: Multifocal

Surgical margins: Close, but negative (to <0.5 mm of the R lobe anterior margin (A1))

Background thyroid: Lymphocytic thyroiditis, nodular hyperplasia.

Lymph nodes: Specimen A: metastatic papillary thyroid carcinoma (1/3)

Total: metastatic papillary thyroid carcinoma (5/7)

Largest metastasis : 1.1 cm (B1)

Extra-nodal extension: present (B1)

AJCC Stage: pT1 pN1 pMx

B: Lymph nodes, right central neck, dissection

- Metastatic papillary thyroid carcinoma (4/4)

Clinical History:

papillary thyroid cancer.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "total thyroid."

Specimen fixation: formalin

Type of specimen: total thyroidectomy

Size and weight of specimen: 6.2 grams; 4.3 cm medial to lateral, 4.9 cm superior to inferior, and 1.2 cm anterior to posterior

Orientation: As per the requisition, the stitch designates the left superior pole. The specimen is inked as follows: posterior=green, anterior=violet, isthmus=yellow.

[page 2 of 2]
Tumor location: right inferior thyroid gland

Tumor description: solitary, rounded, red/tan, gritty cut surface, circumscribed, non-encapsulated

Tumor size: 2 x 1.2 x 1.6 cm

Confinement/non-confinement to the thyroid gland: confined

Distance of tumor from surgical margins: The tumor abuts the anterior and posterior margins of the right thyroid lobe.

Appearance of thyroid gland away from tumor: multinodular appearance

Tissue submitted for special investigations: representative tumor is submitted to Tissue Procurement

Lymph nodes: See Specimen B

Digital photograph taken: no

Block Summary:

A1-A2 - right superior thyroid nodule, submitted in contiguous sections, inferior to superior

A3 - representative right middle thyroid adjacent to right inferior thyroid nodule

A4 - representative right superior thyroid

A5 - isthmus

A6 - representative left thyroid lobe

Tissue remains

Container B is additionally labeled "right central neck dissection." The specimen consists of two red/brown fibrofatty tissue fragments measuring 3.4 x 1.8 x 1.1 cm in aggregate. Isolated from the tissue fragment are four lymph node candidates ranging in size from 1.2 cm to 1.6 cm in greatest dimension. The specimen is otherwise grossly unremarkable.

Block summary:

B1 - one lymph node candidate, trisected

B2 - three lymph node candidates

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed

Signature

Resident Physician:

Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Electronically Signed by:

Source: NCI Genomic Data Commons file 4d2aa0c0-76a6-43ff-9e87-b5bf9a9fe5ae (TCGA-DE-A0XZ.DDD69861-E047-4D17-862A-06626959C9AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).